Somatic mutation profile of tumor specimen TCGA-MT-A7BN-01A (aliquot TCGA-MT-A7BN-01A-12D-A34J-08) from TCGA case TCGA-MT-A7BN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 74.4 years (27,162 days).
Specimen TCGA-MT-A7BN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8295ef26-3522-4a82-9e00-47ea0a0e1719.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MT-A7BN-10A (Blood Derived Normal), aliquot TCGA-MT-A7BN-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55b07d31-e205-4eb6-bad3-8e0b9cd83592

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 44, Silent 14, Nonsense Mutation 4, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSD | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV99472200; called by muse, mutect2, varscan2
- CEP89 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775079961, COSV59863840; called by muse, mutect2, varscan2
- CWF19L2 | c.560C>A p.A187E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs370930551, COSV99979247; called by muse, varscan2
- CYP2B6 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs766630605, COSV57842889; called by muse, mutect2, varscan2
- DAPK3 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1310239166, COSV100009736; called by muse, mutect2, varscan2
- DGKK | c.679T>C p.C227R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1423072073, COSV101053076; called by muse, mutect2, varscan2
- DUOX2 | c.3212A>T p.D1071V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV101199799; called by muse, mutect2
- ELK3 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957685; called by muse, mutect2, varscan2
- FANCB | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60759160; called by muse, mutect2, varscan2
- FGF11 | c.609G>A p.V203= | Splice Region (SNP) | VAF 15/33 reads (45%) | catalogued as rs772998713, COSV99548379; called by muse, mutect2, varscan2
- GDF3 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs1402717557, COSV100325196; called by muse, mutect2, varscan2
- GNB5 | c.667G>A p.D223N (on ENST00000261837 / NM_016194.4; = p.D181N on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs758743901, COSV99953443; called by muse, mutect2, varscan2
- HADHB | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as CM031198, COSV100502055; called by muse, mutect2, varscan2
- HECTD4 | c.12172C>T p.R4058C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66387753; called by muse, mutect2, varscan2
- HERC6 | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.998); catalogued as COSV99910591; called by muse, mutect2, varscan2
- HSP90B1 | c.1644G>A p.E548= | Splice Region (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100236594; called by muse, mutect2, varscan2
- IGSF1 | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812164; called by muse, mutect2, varscan2
- INSRR | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63871330; called by muse, mutect2
- MAGEA10 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV99726767; called by muse, mutect2, varscan2
- MAGI3 | c.2101A>G p.K701E | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs534853362, COSV100289548; called by muse, mutect2, varscan2
- MATN2 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); catalogued as rs775304395, COSV99646271; called by muse, mutect2, varscan2
- MGAM | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV101516455; called by muse, mutect2, varscan2
- MSX1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as rs746116954, COSV101235706, COSV101235709; called by muse, mutect2, varscan2
- NAV2 | c.6766A>C p.T2256P (on ENST00000396087 / NM_001244963.2; = p.T2197P on NM_145117.5) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100217181; called by muse, mutect2, varscan2
- NCKAP1 | c.2411A>T p.H804L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV100720356; called by muse, mutect2, varscan2
- NF1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 56/130 reads (43%) | catalogued as CM1311454, COSV62224610; called by muse, mutect2, varscan2
- NFE2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1565886818, COSV100380773; called by muse, mutect2, varscan2
- NGF | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV101049558, COSV65687627; called by muse, mutect2, varscan2
- PDZRN4 | c.1007C>T p.T336M (on ENST00000402685 / NM_001164595.2; = p.T78M on NM_013377.4) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549596773, COSV100114809; called by muse, mutect2, varscan2
- PKHD1L1 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs369930599; called by muse, mutect2, varscan2
- PSG3 | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV100549063, COSV59503236; called by mutect2, varscan2
- RAB6C | c.429G>C p.R143S | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.035); catalogued as COSV101308520, COSV69339914; called by muse, mutect2, varscan2
- RBM28 | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 17/125 reads (14%) | catalogued as rs770885287, COSV56163264; called by muse, mutect2, varscan2
- RHBDF1 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs143220179; called by muse, mutect2, varscan2
- RRNAD1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.856); catalogued as rs1357101992, COSV100494041; called by muse, mutect2, varscan2
- SHC3 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV101011963; called by muse, mutect2, varscan2
- SLC7A10 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53504802, COSV99472331; called by muse, mutect2
- STAG3 | c.2926C>T p.R976C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751623475, COSV100426010; called by muse, mutect2, varscan2
- SYCP2 | c.2084A>G p.Q695R | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.648); catalogued as COSV100698320; called by muse, mutect2, varscan2
- TAS2R9 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.338); catalogued as rs772693833, COSV99553840; called by muse, mutect2, varscan2
- TATDN1 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 56/178 reads (31%) | catalogued as COSV99413478; called by muse, mutect2, varscan2
- TMPRSS11B | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100219417; called by muse, mutect2, varscan2
- TMTC3 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV99898451; called by muse, mutect2, varscan2
- TP53 | c.642del p.H214Qfs*33 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | catalogued as COSV52806263, COSV52926654, COSV53527694; called by mutect2, pindel, varscan2
- TTN | c.71852C>A p.A23951D (on ENST00000591111; = p.A16527D on NM_003319.4) | Missense Mutation (SNP) | VAF 34/186 reads (18%) | PolyPhen possibly damaging (0.463); catalogued as COSV100618266; called by muse, mutect2, varscan2
- UNC45B | c.2655G>C p.K885N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99268820; called by muse, mutect2, varscan2
- VAV1 | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535090610, COSV100409172; called by muse, mutect2, varscan2
- ZNF407 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs773572221, COSV55264680; called by muse, mutect2, varscan2
- ZNF76 | c.1585A>C p.N529H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99987755; called by muse, mutect2, varscan2
- ZP4 | c.1271T>A p.F424Y | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100850705; called by muse, mutect2
- COL6A3 | c.9046G>A p.G3016S | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE4DIP | c.1615_1616dup p.S539Rfs*4 | Frame Shift Ins (INS) | VAF 72/270 reads (27%) | called by mutect2, varscan2
- PTEN | c.878_881del p.G293Vfs*13 | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | called by mutect2, pindel, varscan2
- CACNA1A | c.666G>A p.A222= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1291660477, COSV100802677, COSV64204219; called by muse, mutect2, varscan2
- CLIP3 | c.1383C>T p.V461= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs781410612, COSV99431150; called by muse, varscan2
- FDX1 | c.492T>C p.T164= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99501879; called by muse, mutect2, varscan2
- GLOD4 | c.318C>T p.L106= (on ENST00000301328 / NM_001366247.1; = p.L91= on NM_016080.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs754682367, COSV100022642, COSV56753560; called by muse, mutect2, varscan2
- MAGEB6B | c.1023C>T p.Y341= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs1462976220, COSV101301708; called by muse, mutect2, varscan2
- MGP | c.51T>G p.T17= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99967146; called by muse, mutect2, varscan2
- NLRP7 | c.2814G>A p.L938= (on ENST00000340844 / NM_206828.3; = p.L967= on NM_139176.3) | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV100052894; called by muse, varscan2
- NUTM1 | c.1998T>G p.G666= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100149066; called by muse, mutect2, varscan2
- OR2M7 | c.273C>A p.S91= | Silent (SNP) | VAF 59/477 reads (12%) | catalogued as COSV100522594; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1404C>T p.Y468= (on ENST00000352766; = p.Y389= on NM_181334.5) | Silent (SNP) | VAF 82/143 reads (57%) | catalogued as rs528651618, COSV61233508; called by muse, mutect2, varscan2
- PRUNE2 | c.7372C>T p.L2458= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100944755; called by muse, mutect2
- PTPRH | c.312C>T p.D104= | Silent (SNP) | VAF 51/287 reads (18%) | catalogued as rs758311383, COSV54743061; called by muse, mutect2, varscan2
- TAOK2 | c.1080C>T p.S360= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as rs757491664, COSV99664891; called by muse, mutect2, varscan2
- TMEM31 | c.369C>A p.I123= | Silent (SNP) | VAF 60/84 reads (71%) | catalogued as COSV100129041; called by muse, mutect2, varscan2
